Somatic mutation profile of tumor specimen TCGA-GS-A9TT-01A (aliquot TCGA-GS-A9TT-01A-11D-A382-10) from TCGA case TCGA-GS-A9TT, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Diffuse large B-cell lymphoma, NOS; Tissue or organ of origin: Testis, NOS; Age at diagnosis: 70.6 years (25,794 days).
Specimen TCGA-GS-A9TT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 17bd23e2-e021-452e-9eee-8ce3299fde5e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GS-A9TT-10A (Blood Derived Normal), aliquot TCGA-GS-A9TT-10A-01D-A385-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4d39b51d-4da4-47c5-b415-34e238f4d901

The open-access MAF lists 231 somatic variants for this specimen: 169 protein-altering or splice-affecting, 58 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 144, Silent 58, Nonsense Mutation 13, Frame Shift Del 5, Splice Site 2, Intron 2, Frame Shift Ins 2, Splice Region 2, In Frame Del 1, 3'Flank 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIM1 | c.111G>T p.Q37H | Missense Mutation (SNP) | VAF 18/42 reads (43%) | hotspot (GDC flag); SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV65165508, COSV65166397, COSV65166671; called by muse, varscan2
- PIM1 | c.237G>C p.E79D | Missense Mutation (SNP) | VAF 31/63 reads (49%) | hotspot (GDC flag); SIFT tolerated (0.19); PolyPhen benign (0.031); catalogued as COSV100998754, COSV65164441, COSV65164484; called by muse, varscan2
- ABCD4 | c.1441G>T p.V481F | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.257); catalogued as rs1279658942, COSV100084309; called by muse, mutect2, varscan2
- ACTG1 | c.279G>C p.E93D | Missense Mutation (SNP) | VAF 51/93 reads (55%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.945); catalogued as rs782165228, COSV59509829; called by muse, mutect2, varscan2
- ADAMTS18 | c.92C>T p.A31V | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.49); PolyPhen benign (0.148); catalogued as rs377554176; called by mutect2, varscan2
- ADGRA3 | c.3628C>T p.R1210W | Missense Mutation (SNP) | VAF 84/184 reads (46%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.609); catalogued as rs779659276, COSV99293323; called by muse, mutect2, varscan2
- AGTR2 | c.401T>G p.F134C | Missense Mutation (SNP) | VAF 216/234 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100903575, COSV100903639; called by muse, mutect2, varscan2
- AMOTL1 | c.1735G>A p.E579K | Missense Mutation (SNP) | VAF 34/53 reads (64%) | SIFT deleterious (0.03); PolyPhen benign (0.051); catalogued as rs566138044, COSV100504429; called by muse, varscan2
- ARHGAP45 | c.2053G>T p.A685S | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.225); catalogued as COSV100490738; called by muse, mutect2, varscan2
- ARHGEF3 | c.1333C>T p.R445C | Missense Mutation (SNP) | VAF 112/242 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs866259310, COSV56323686; called by muse, varscan2
- ASB11 | c.874C>T p.R292C | Missense Mutation (SNP) | VAF 63/65 reads (97%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773872197, COSV100729032; called by muse, mutect2, varscan2
- BPTF | c.8551A>T p.K2851* | Nonsense Mutation (SNP) | VAF 76/150 reads (51%) | catalogued as COSV100075033; called by muse, mutect2, varscan2
- BRINP2 | c.1742C>A p.T581N | Missense Mutation (SNP) | VAF 42/82 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100838103, COSV100838109; called by muse, mutect2, varscan2
- BTG2 | c.142G>T p.E48* | Nonsense Mutation (SNP) | VAF 30/64 reads (47%) | catalogued as rs753317706, COSV51855284, COSV51857385, COSV99305778; called by muse, varscan2
- BTG2 | c.142+1G>A p.X48_splice | Splice Site (SNP) | VAF 32/64 reads (50%) | catalogued as rs1270109023, COSV51857137; called by muse, varscan2
- BTNL3 | c.278C>T p.A93V | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.027); catalogued as rs1384110022, COSV100732210; called by mutect2, varscan2
- C20orf194 | c.1311-1G>T p.X437_splice | Splice Site (SNP) | VAF 16/42 reads (38%) | catalogued as COSV99330787; called by muse, mutect2, varscan2
- CALHM2 | c.545A>T p.Y182F | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.528); catalogued as COSV99588638; called by muse, varscan2
- CCDC89 | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 41/87 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.017); catalogued as rs777244675, COSV100320857; called by muse, mutect2, varscan2
- CD70 | c.527T>A p.L176* | Nonsense Mutation (SNP) | VAF 21/33 reads (64%) | catalogued as COSV99835585; called by muse, mutect2, varscan2
- CES1 | c.80A>T p.D27V | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.621); catalogued as COSV62086270; called by muse, mutect2, varscan2
- CIITA | c.52G>A p.G18S | Missense Mutation (SNP) | VAF 53/119 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as rs912486797, COSV100161987, COSV60855449; called by muse, mutect2, varscan2
- CILP2 | c.2896C>T p.R966C | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.39); catalogued as rs1295996198, COSV99364719; called by muse, mutect2, varscan2
- COL11A1 | c.2171G>T p.G724V | Missense Mutation (SNP) | VAF 155/374 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100615437; called by muse, mutect2, varscan2
- COL12A1 | c.1917T>G p.S639R | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV100486028; called by muse, mutect2, varscan2
- CSMD1 | c.6841G>T p.D2281Y (on ENST00000520002; = p.D2280Y on NM_033225.6) | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59288692, COSV59383511; called by muse, mutect2, varscan2
- CUL1 | c.344T>C p.V115A | Missense Mutation (SNP) | VAF 45/124 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as rs1238150632, COSV100296685; called by muse, mutect2, varscan2
- CYLC1 | c.280G>T p.A94S | Missense Mutation (SNP) | VAF 134/146 reads (92%) | SIFT tolerated (0.07); PolyPhen benign (0.058); catalogued as COSV100254692; called by muse, mutect2, varscan2
- DGCR8 | c.1423C>T p.Q475* | Nonsense Mutation (SNP) | VAF 26/54 reads (48%) | catalogued as COSV100707971; called by muse, mutect2, varscan2
- DSC3 | c.1727A>T p.E576V | Missense Mutation (SNP) | VAF 54/208 reads (26%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV100844609; called by muse, mutect2, varscan2
- DUOX1 | c.2512C>T p.R838* | Nonsense Mutation (SNP) | VAF 12/88 reads (14%) | catalogued as rs143543011; called by muse, mutect2, varscan2
- EHMT1 | c.3497A>T p.D1166V | Missense Mutation (SNP) | VAF 79/188 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV101509677; called by muse, mutect2, varscan2
- EIF2S2 | c.854G>A p.R285Q | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV66621250; called by muse, mutect2, varscan2
- ESR2 | c.62C>T p.S21F | Missense Mutation (SNP) | VAF 69/137 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99963290; called by muse, mutect2, varscan2
- ESRRG | c.1240G>C p.A414P | Missense Mutation (SNP) | VAF 65/145 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.593); catalogued as COSV100752989; called by muse, mutect2, varscan2
- F11 | c.281C>T p.A94V | Missense Mutation (SNP) | VAF 79/204 reads (39%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); catalogued as rs367856671; called by muse, mutect2, varscan2
- FANCD2 | c.521G>A p.R174Q | Missense Mutation (SNP) | VAF 53/117 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.545); catalogued as rs41291203; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FAT2 | c.8389T>C p.F2797L | Missense Mutation (SNP) | VAF 50/93 reads (54%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.99); catalogued as COSV99942976; called by muse, mutect2, varscan2
- FAT4 | c.4338C>G p.D1446E | Missense Mutation (SNP) | VAF 42/90 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101272357; called by muse, mutect2, varscan2
- FCGBP | c.4787C>T p.P1596L | Missense Mutation (SNP) | VAF 113/582 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.114); catalogued as rs587653757; called by muse, mutect2, varscan2
- FOXA3 | c.730G>A p.A244T | Missense Mutation (SNP) | VAF 22/33 reads (67%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs775453392, COSV100141398; called by muse, mutect2, varscan2
- FOXS1 | c.278C>T p.T93M | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as rs140637242; called by muse, mutect2, varscan2
- FZD7 | c.109G>A p.G37R | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as COSV99637231; called by muse, mutect2, varscan2
- GATA3 | c.481G>A p.V161I | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.041); catalogued as rs1158297550, COSV100651015; called by muse, mutect2, varscan2
- GSTA3 | c.664T>G p.F222V | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as COSV99274553; called by muse, mutect2, varscan2
- H2AC17 | c.379G>C p.A127P | Missense Mutation (SNP) | VAF 85/181 reads (47%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs191325870, COSV58152870; called by muse, mutect2, varscan2
- H2BC11 | c.310C>A p.P104T | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV100345763, COSV100345829; called by muse, mutect2, varscan2
- HDAC8 | c.1082G>A p.R361Q | Missense Mutation (SNP) | VAF 57/65 reads (88%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs781862582, COSV104424088, COSV65265941; called by muse, mutect2, varscan2
- HNRNPA1 | c.877G>T p.G293* | Nonsense Mutation (SNP) | VAF 31/88 reads (35%) | catalogued as COSV99267662; called by muse, mutect2, varscan2
- HSPA1L | c.830C>T p.S277L | Missense Mutation (SNP) | VAF 58/123 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1460318497, COSV65148955; called by muse, mutect2, varscan2
- IGHG1 | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs778744453; called by muse, varscan2
- IGHV2-26 | c.88C>G p.L30V | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.023); catalogued as rs563075390; called by muse, mutect2
- IGHV2-70 | c.125C>G p.T42S | Missense Mutation (SNP) | VAF 86/185 reads (46%) | SIFT tolerated (0.53); PolyPhen benign (0.061); catalogued as rs369724963; called by muse, varscan2
- IGHV3-7 | c.302A>T p.Q101L | Missense Mutation (SNP) | VAF 64/108 reads (59%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.916); catalogued as rs375250499; called by muse, varscan2
- IGKV1-5 | c.170G>C p.W57S | Missense Mutation (SNP) | VAF 68/86 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs770011436; called by muse, varscan2
- IGKV1-5 | c.124A>T p.T42S | Missense Mutation (SNP) | VAF 62/72 reads (86%) | SIFT tolerated (0.14); PolyPhen benign (0.257); catalogued as rs768302130; called by muse, varscan2
- IGKV4-1 | c.78G>C p.Q26H | Missense Mutation (SNP) | VAF 57/64 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745767076; called by muse, mutect2, varscan2
- IGLV2-8 | c.218G>C p.S73T | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.007); catalogued as rs11558646; called by muse, mutect2, varscan2
- IGLV3-1 | c.334A>T p.S112C | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs370589387; called by muse, varscan2
- IGLV3-1 | c.335G>T p.S112I | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.729); catalogued as rs374018767; called by muse, varscan2
- IGLV4-60 | c.335A>C p.Y112S | Missense Mutation (SNP) | VAF 24/37 reads (65%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); catalogued as rs568573758, COSV101135221; called by muse, mutect2, varscan2
- IRF2BP2 | c.988G>A p.A330T | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV100784324, COSV64014585; called by muse, mutect2, varscan2
- ITPKB | c.595G>T p.E199* | Nonsense Mutation (SNP) | VAF 22/44 reads (50%) | catalogued as COSV99684493; called by muse, mutect2, varscan2
- JAM3 | c.900C>T p.G300= | Splice Region (SNP) | VAF 60/132 reads (45%) | catalogued as rs200279211, COSV100138201; called by muse, mutect2, varscan2
- KANK4 | c.1231G>C p.D411H | Missense Mutation (SNP) | VAF 52/123 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.921); catalogued as COSV100587388, COSV62985555; called by muse, mutect2, varscan2
- KBTBD13 | c.1102G>A p.A368T | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV101416692; called by muse, mutect2, varscan2
- KCNA3 | c.869G>A p.S290N | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (0.48); PolyPhen benign (0.027); catalogued as COSV100871266; called by muse, mutect2, varscan2
- KDR | c.822C>A p.N274K | Missense Mutation (SNP) | VAF 64/155 reads (41%) | SIFT tolerated (0.91); PolyPhen benign (0.243); catalogued as COSV99817806; called by muse, mutect2, varscan2
- KLHL21 | c.492C>A p.H164Q | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.67); catalogued as rs531955371, COSV100887246; called by muse, varscan2
- KLHL21 | c.480C>A p.F160L | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); catalogued as COSV100887247; called by muse, varscan2
- LAMA3 | c.782G>A p.R261H | Missense Mutation (SNP) | VAF 83/249 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0.015); catalogued as rs777581271, COSV58070038; called by muse, mutect2, varscan2
- LILRA2 | c.802G>T p.G268C | Missense Mutation (SNP) | VAF 42/129 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.685); catalogued as COSV99253417; called by muse, varscan2
- LIMD1 | c.85T>C p.F29L | Missense Mutation (SNP) | VAF 32/38 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs762091224, COSV99836966; called by muse, mutect2, varscan2
- LIN28B | c.521C>T p.A174V | Missense Mutation (SNP) | VAF 29/33 reads (88%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs201716597, COSV100558834; called by muse, mutect2, varscan2
- LMF1 | c.1375C>T p.H459Y | Missense Mutation (SNP) | VAF 34/62 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV99235231; called by muse, mutect2, varscan2
- MAPK8IP3 | c.3212A>G p.Q1071R | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV99168816; called by muse, mutect2
- MBOAT2 | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 202/419 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.802); catalogued as rs955335450, COSV60012040; called by muse, mutect2, varscan2
- MMP16 | c.1057C>A p.L353I | Missense Mutation (SNP) | VAF 57/118 reads (48%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.769); catalogued as COSV99688422; called by muse, mutect2, varscan2
- MYH2 | c.3800C>A p.S1267* | Nonsense Mutation (SNP) | VAF 43/100 reads (43%) | catalogued as COSV99820220; called by muse, mutect2, varscan2
- MYO5B | c.678T>G p.I226M | Missense Mutation (SNP) | VAF 37/156 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV99545072; called by muse, mutect2, varscan2
- NCAM2 | c.132G>A p.A44= | Splice Region (SNP) | VAF 41/78 reads (53%) | catalogued as rs942523925, COSV53086652, COSV53101523; called by muse, mutect2, varscan2
- NECAB3 | c.1033C>A p.L345M (on ENST00000246190 / NM_031232.4; = p.L311M on NM_031231.4) | Missense Mutation (SNP) | VAF 36/67 reads (54%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.525); catalogued as COSV99864797; called by muse, mutect2, varscan2
- NIPA2 | c.1046A>G p.N349S | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV100488269; called by muse, mutect2, varscan2
- NISCH | c.2462G>T p.S821I | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT tolerated (0.22); PolyPhen benign (0.045); catalogued as COSV100617371; called by muse, mutect2, varscan2
- NOL9 | c.323A>T p.H108L | Missense Mutation (SNP) | VAF 91/206 reads (44%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV100063116; called by muse, mutect2, varscan2
- NPHS1 | c.718C>T p.P240S | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100799904; called by muse, mutect2, varscan2
- NUAK1 | c.1700G>A p.R567H | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); catalogued as rs752050315, COSV54602918; called by muse, mutect2, varscan2
- NUF2 | c.1202T>C p.I401T | Missense Mutation (SNP) | VAF 117/264 reads (44%) | SIFT tolerated (0.51); PolyPhen benign (0.035); catalogued as COSV99616525; called by muse, mutect2, varscan2
- NUP153 | c.2801T>G p.I934R | Missense Mutation (SNP) | VAF 52/120 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.095); catalogued as COSV100020348; called by muse, mutect2, varscan2
- OR1M1 | c.240G>T p.K80N | Missense Mutation (SNP) | VAF 68/138 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV101447559; called by muse, mutect2, varscan2
- OR5L1 | c.772A>G p.I258V | Missense Mutation (SNP) | VAF 44/88 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV100450060; called by muse, mutect2
- OR5M10 | c.53C>G p.T18R | Missense Mutation (SNP) | VAF 60/144 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as COSV101595887; called by muse, mutect2, varscan2
- OR6B3 | c.522G>T p.L174F | Missense Mutation (SNP) | VAF 66/141 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV100097258; called by muse, mutect2, varscan2
- OR6K6 | c.257C>A p.P86H (on ENST00000368144; = p.P62H on NM_001005184.1) | Missense Mutation (SNP) | VAF 68/178 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100933744; called by muse, mutect2, varscan2
- OR9A4 | c.116T>C p.M39T | Missense Mutation (SNP) | VAF 87/187 reads (47%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as COSV101516440; called by muse, mutect2, varscan2
- OSBPL10 | c.281G>A p.R94K | Missense Mutation (SNP) | VAF 38/72 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as COSV64383923; called by muse, varscan2
- OSBPL10 | c.252C>A p.Y84* | Nonsense Mutation (SNP) | VAF 34/80 reads (43%) | catalogued as COSV100824413; called by muse, varscan2
- OSBPL10 | c.241C>T p.L81F | Missense Mutation (SNP) | VAF 38/77 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1235180018, COSV100824414, COSV64384274; called by muse, varscan2
- OSBPL10 | c.98G>A p.C33Y | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); catalogued as COSV100824418; called by muse, varscan2
- OSBPL10 | c.71C>A p.A24D | Missense Mutation (SNP) | VAF 50/94 reads (53%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.059); catalogued as COSV100824360, COSV100824423; called by muse, varscan2
- OSBPL10 | c.59G>A p.S20N | Missense Mutation (SNP) | VAF 45/106 reads (42%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.431); catalogued as COSV100824424; called by muse, varscan2
- OSBPL10 | c.53G>A p.S18N | Missense Mutation (SNP) | VAF 56/105 reads (53%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.023); catalogued as COSV100824425; called by muse, varscan2
- OSBPL10 | c.41G>C p.S14T | Missense Mutation (SNP) | VAF 44/111 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.31); catalogued as COSV100824426; called by muse, varscan2
- OTX2 | c.659G>C p.S220T (on ENST00000408990 / NM_172337.3; = p.S228T on NM_021728.4) | Missense Mutation (SNP) | VAF 70/141 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as COSV100257951; called by muse, mutect2, varscan2
- PARD3 | c.3226C>T p.R1076* | Nonsense Mutation (SNP) | VAF 42/99 reads (42%) | catalogued as rs1342213201, COSV100632117; called by muse, mutect2, varscan2
- PCDH1 | c.1705T>A p.S569T | Missense Mutation (SNP) | VAF 40/62 reads (65%) | SIFT tolerated (0.49); PolyPhen benign (0.103); catalogued as rs1160536619, COSV99746279; called by muse, mutect2, varscan2
- PDE3A | c.1931A>G p.E644G | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.614); catalogued as COSV100762161; called by muse, mutect2, varscan2
- PHF2 | c.907T>A p.Y303N | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100823176; called by muse, mutect2, varscan2
- PIK3AP1 | c.1202T>G p.L401R | Missense Mutation (SNP) | VAF 41/121 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100225798; called by muse, mutect2
- PIM1 | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.51); PolyPhen benign (0.006); catalogued as rs775870535, COSV65166500, COSV65166793; called by muse, varscan2
- PIM1 | c.125C>T p.P42L | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.344); catalogued as COSV100998676; called by muse, varscan2
- PIM1 | c.384T>A p.D128E | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV100998678; called by muse, varscan2
- PIM1 | c.385C>G p.L129V | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100998563, COSV100998679; called by muse, varscan2
- PIM1 | c.549G>C p.K183N | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as COSV100998684, COSV65166573; called by muse, varscan2
- PLCG2 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV63871962, COSV63873535; called by muse, mutect2, varscan2
- PLEKHM3 | c.602G>T p.G201V | Missense Mutation (SNP) | VAF 52/131 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.685); catalogued as COSV101216592; called by muse, mutect2, varscan2
- POLR1A | c.1448C>T p.A483V | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs775273706, COSV55699534; called by muse, varscan2
- PRDM9 | c.2180G>A p.R727Q | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0.153); catalogued as rs760843262, COSV57003225; called by muse, mutect2, varscan2
- PRICKLE2 | c.2207G>A p.R736H (on ENST00000295902; = p.R680H on NM_198859.4) | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.742); catalogued as rs1308230146, COSV99897346; called by muse, mutect2, varscan2
- PRRT3 | c.94A>G p.R32G | Missense Mutation (SNP) | VAF 36/68 reads (53%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV99926530; called by muse, mutect2
- PTPN18 | c.1327C>T p.R443C | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768555515, COSV51558757; called by muse, mutect2, varscan2
- PTPN6 | c.175G>A p.D59N | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.875); catalogued as COSV100017118; called by muse, mutect2, varscan2
- PTPRF | c.4594C>T p.R1532W | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748151594, COSV100740936; called by muse, mutect2, varscan2
- PTPRZ1 | c.3188T>G p.V1063G | Missense Mutation (SNP) | VAF 54/106 reads (51%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as rs750687472, COSV101100154; called by muse, mutect2, varscan2
- RASL10A | c.395A>G p.D132G | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99329533; called by muse, varscan2
- RBBP7 | c.248T>G p.V83G | Missense Mutation (SNP) | VAF 165/181 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101198287; called by muse, mutect2, varscan2
- RCC1L | c.115G>T p.A39S | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.548); catalogued as COSV100326906; called by muse, mutect2, varscan2
- REEP2 | c.453G>A p.M151I | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.168); catalogued as COSV99649629; called by mutect2, varscan2
- RNF113B | c.443G>A p.R148Q | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV57434888; called by muse, mutect2, varscan2
- ROS1 | c.2903T>C p.L968P | Missense Mutation (SNP) | VAF 60/78 reads (77%) | SIFT deleterious (0.04); PolyPhen benign (0.229); catalogued as COSV100877114; called by muse, mutect2, varscan2
- SEL1L2 | c.879A>T p.E293D | Missense Mutation (SNP) | VAF 84/185 reads (45%) | SIFT tolerated (0.82); PolyPhen probably damaging (0.97); catalogued as COSV99533271; called by muse, mutect2, varscan2
- SH3BGRL2 | c.13G>A p.V5M | Missense Mutation (SNP) | VAF 53/133 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.529); catalogued as COSV100877618; called by muse, mutect2, varscan2
- SLC12A1 | c.371C>A p.P124H | Missense Mutation (SNP) | VAF 39/44 reads (89%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV57708002; called by muse, mutect2, varscan2
- SLITRK1 | c.794A>C p.N265T | Missense Mutation (SNP) | VAF 65/136 reads (48%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV100999970; called by muse, mutect2, varscan2
- SOCS1 | c.419G>C p.S140T | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.374); catalogued as COSV100130353; called by muse, varscan2
- SOD3 | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV101181096; called by muse, mutect2, varscan2
- SPHKAP | c.3020C>T p.T1007M | Missense Mutation (SNP) | VAF 54/121 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs752182241, COSV60868700; called by muse, mutect2, varscan2
- STAC | c.68A>G p.E23G | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.073); catalogued as COSV99830078; called by muse, mutect2, varscan2
- STX16 | c.103A>G p.S35G | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.107); catalogued as COSV100397434; called by muse, mutect2
- SYNE2 | c.13754A>G p.K4585R | Missense Mutation (SNP) | VAF 51/93 reads (55%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.767); catalogued as COSV100647747; called by muse, mutect2, varscan2
- TBL1XR1 | c.974G>T p.C325F | Missense Mutation (SNP) | VAF 92/97 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70499648, COSV70501007, COSV70504550; called by muse, mutect2, varscan2
- TEKT1 | c.376G>T p.D126Y | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100106231; called by muse, mutect2, varscan2
- TIAM1 | c.1438G>A p.D480N | Missense Mutation (SNP) | VAF 45/89 reads (51%) | SIFT tolerated (0.66); PolyPhen probably damaging (0.998); catalogued as rs771808182, COSV99735379; called by muse, mutect2, varscan2
- TRAPPC8 | c.1964A>T p.Q655L | Missense Mutation (SNP) | VAF 26/340 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV99351306; called by muse, mutect2
- TRIOBP | c.5902C>T p.R1968C (on ENST00000644935 / NM_001039141.3; = p.R255C on NM_007032.5) | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.93); catalogued as rs774618582, COSV100462307; called by muse, mutect2, varscan2
- VAT1 | c.28G>A p.A10T | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT tolerated (0.53); PolyPhen benign (0.039); catalogued as COSV100849723; called by muse, mutect2, varscan2
- VMP1 | c.991G>A p.G331S | Missense Mutation (SNP) | VAF 103/209 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV51867177, COSV99230468; called by muse, mutect2, varscan2
- VMP1 | c.1130G>T p.C377F | Missense Mutation (SNP) | VAF 146/310 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as COSV51868631; called by muse, varscan2
- WNK2 | c.3056C>G p.P1019R | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.134); catalogued as COSV99942565; called by muse, mutect2
- ZCCHC8 | c.1888G>A p.V630I | Missense Mutation (SNP) | VAF 154/257 reads (60%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1200474022, COSV100288678; called by muse, mutect2, varscan2
- ZMYM2 | c.3131del p.K1044Rfs*33 | Frame Shift Del (DEL) | VAF 26/57 reads (46%) | catalogued as rs753611080; called by mutect2, varscan2
- ZNF43 | c.1020A>C p.K340N | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.555); catalogued as COSV100731826; called by muse, mutect2, varscan2
- ZNF493 | c.1895A>C p.K632T | Missense Mutation (SNP) | VAF 64/142 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.389); catalogued as COSV100828716; called by muse, mutect2
- ZNF518A | c.3320T>A p.L1107* | Nonsense Mutation (SNP) | VAF 58/205 reads (28%) | catalogued as rs782169664, COSV100283539, COSV60151512; called by muse, mutect2, varscan2
- ZNF608 | c.838A>T p.M280L | Missense Mutation (SNP) | VAF 57/133 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100101694; called by muse, mutect2, varscan2
- ZNF700 | c.492T>G p.Y164* | Nonsense Mutation (SNP) | VAF 62/123 reads (50%) | catalogued as COSV54314582, COSV99583542; called by muse, mutect2, varscan2
- ZNF827 | c.886G>A p.A296T | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs965410329, COSV101061378; called by muse, varscan2
- ARHGAP21 | c.1145_1146insC p.Q382Hfs*9 | Frame Shift Ins (INS) | VAF 52/120 reads (43%) | called by mutect2, pindel*, varscan2*
- BCOR | c.5159del p.S1720Ifs*5 (on ENST00000378444 / NM_001123385.2; = p.S1686Ifs*5 on NM_017745.6) | Frame Shift Del (DEL) | VAF 126/199 reads (63%) | called by pindel, varscan2
- CIITA | c.1342_1343del p.V448Lfs*34 | Frame Shift Del (DEL) | VAF 31/68 reads (46%) | called by mutect2, pindel, varscan2
- IGHG1 | c.460C>T p.P154S | Missense Mutation (SNP) | VAF 47/94 reads (50%) | SIFT tolerated (0.17); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- IGHG1 | c.292G>C p.V98L | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, varscan2
- IGHG1 | c.279G>C p.K93N | Missense Mutation (SNP) | VAF 46/100 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.366); called by muse, varscan2
- IGHG1 | c.151C>T p.H51Y | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.227); called by muse, varscan2
- IGKV1-5 | c.171G>A p.W57* | Nonsense Mutation (SNP) | VAF 69/88 reads (78%) | called by muse, varscan2
- MCUB | c.709_714del p.W237_L238del | In Frame Del (DEL) | VAF 69/202 reads (34%) | called by mutect2, pindel, varscan2
- MYO9B | c.4058_4059insGC p.S1354Pfs*100 | Frame Shift Ins (INS) | VAF 15/47 reads (32%) | called by mutect2, pindel, varscan2
- OSBPL3 | c.2510_2513del p.R837Kfs*6 | Frame Shift Del (DEL) | VAF 83/174 reads (48%) | called by mutect2, pindel, varscan2
- TAS2R19 | c.865_866del p.T289Lfs*? | Frame Shift Del (DEL) | VAF 33/86 reads (38%) | called by pindel, varscan2
- ABHD3 | c.240C>T p.Y80= | Silent (SNP) | VAF 33/97 reads (34%) | catalogued as rs1365935103, COSV100004395; called by muse, mutect2, varscan2
- ALG8 | c.1323T>C p.S441= | Silent (SNP) | VAF 112/217 reads (52%) | catalogued as COSV100220109; called by muse, mutect2, varscan2
- ANKRD11 | c.4548C>T p.D1516= | Silent (SNP) | VAF 55/145 reads (38%) | catalogued as COSV99969424; called by muse, mutect2, varscan2
- APOL2 | c.885A>T p.S295= | Silent (SNP) | VAF 72/146 reads (49%) | catalogued as COSV99969142; called by muse, mutect2, varscan2
- BCR | c.171C>T p.I57= | Silent (SNP) | VAF 31/71 reads (44%) | catalogued as rs952644575, COSV59933271, COSV59934216, COSV59934338; called by muse, varscan2
- BCR | c.175C>T p.L59= | Silent (SNP) | VAF 30/71 reads (42%) | catalogued as rs760439736, COSV100006564, COSV104400323; called by muse, varscan2
- BCR | c.184T>C p.L62= | Silent (SNP) | VAF 37/75 reads (49%) | catalogued as COSV100006565; called by muse, varscan2
- CFAP47 | c.822T>C p.N274= | Silent (SNP) | VAF 181/200 reads (91%) | catalogued as rs988916500, COSV99935106; called by muse, mutect2, varscan2
- COL21A1 | c.2466C>T p.S822= | Silent (SNP) | VAF 96/204 reads (47%) | catalogued as COSV99777785, COSV99778836; called by muse, mutect2, varscan2
- COQ8B | c.303C>A p.G101= | Silent (SNP) | VAF 68/106 reads (64%) | catalogued as COSV99699434; called by muse, mutect2, varscan2
- DNAH7 | c.1359T>C p.S453= | Silent (SNP) | VAF 78/195 reads (40%) | catalogued as COSV100415338; called by muse, mutect2, varscan2
- ENPEP | c.519G>A p.A173= | Silent (SNP) | VAF 26/58 reads (45%) | catalogued as rs373421438, COSV99487634; called by muse, mutect2, varscan2
- FAT3 | c.10899G>C p.V3633= | Silent (SNP) | VAF 28/64 reads (44%) | catalogued as COSV99966484; called by muse, mutect2
- FNDC3B | c.1083C>T p.S361= | Silent (SNP) | VAF 39/78 reads (50%) | catalogued as rs756597691, COSV100394220, COSV61039637; called by muse, mutect2, varscan2
- FOXB2 | c.1131G>A p.A377= | Silent (SNP) | VAF 23/47 reads (49%) | catalogued as COSV100942346; called by muse, mutect2, varscan2
- GASK1B | c.369C>A p.G123= | Silent (SNP) | VAF 23/61 reads (38%) | catalogued as COSV99647642; called by muse, mutect2, varscan2
- H2BC5 | c.327G>A p.K109= | Silent (SNP) | VAF 46/101 reads (46%) | catalogued as COSV56804285; called by muse, mutect2, varscan2
- HELZ2 | c.4407G>A p.P1469= (on ENST00000467148 / NM_001037335.2; = p.P900= on NM_033405.3) | Silent (SNP) | VAF 12/19 reads (63%) | catalogued as rs903203958, COSV101427570; called by muse, mutect2, varscan2
- IDO1 | c.735C>T p.D245= | Silent (SNP) | VAF 65/155 reads (42%) | catalogued as rs775200359, COSV99503369; called by muse, mutect2, varscan2
- IGHV1-69 | c.150C>T p.S50= | Silent (SNP) | VAF 18/20 reads (90%) | catalogued as rs11546800; called by mutect2, varscan2
- IGHV2-26 | c.42T>C p.P14= | Silent (SNP) | VAF 32/99 reads (32%) | called by muse, varscan2
- IGLV3-1 | c.258G>C p.G86= | Silent (SNP) | VAF 33/68 reads (49%) | catalogued as rs61731682; called by muse, varscan2
- ITIH2 | c.2010C>A p.A670= | Silent (SNP) | VAF 31/73 reads (42%) | catalogued as COSV64434956; called by muse, mutect2, varscan2
- KDM2B | c.2460G>A p.S820= | Silent (SNP) | VAF 13/13 reads (100%) | catalogued as COSV100997189; called by muse, mutect2, varscan2
- KIF17 | c.945G>A p.A315= | Silent (SNP) | VAF 50/119 reads (42%) | catalogued as rs373442401; called by muse, mutect2, varscan2
- KLHL1 | c.1558T>C p.L520= | Silent (SNP) | VAF 64/143 reads (45%) | catalogued as rs772972080, COSV100917344; called by muse, mutect2, varscan2
- KLHL21 | c.502C>T p.L168= | Silent (SNP) | VAF 8/13 reads (62%) | catalogued as COSV100887244; called by muse, varscan2
- LHX5 | c.852C>T p.G284= | Silent (SNP) | VAF 28/41 reads (68%) | catalogued as COSV55661785; called by muse, mutect2, varscan2
- LRRTM4 | c.915C>A p.S305= | Silent (SNP) | VAF 42/92 reads (46%) | catalogued as COSV101297550, COSV69143096; called by muse, mutect2, varscan2
- MAGI2 | c.186G>A p.S62= | Silent (SNP) | VAF 19/44 reads (43%) | catalogued as COSV62633202, COSV62706246; called by muse, mutect2, varscan2
- MATN4 | c.1827G>A p.A609= (on ENST00000372754; = p.A568= on NM_003833.4) | Silent (SNP) | VAF 4/43 reads (9%) | catalogued as COSV100637034; called by mutect2, varscan2
- MYH2 | c.4099C>T p.L1367= | Silent (SNP) | VAF 72/166 reads (43%) | catalogued as rs757447438, COSV99820219; called by muse, mutect2, varscan2
- NOL9 | c.19C>T p.L7= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as COSV100063117; called by muse, mutect2, varscan2
- OSBPL10 | c.126C>T p.S42= | Silent (SNP) | VAF 26/62 reads (42%) | catalogued as rs977792480, COSV100824415; called by muse, varscan2
- OSBPL10 | c.99C>T p.C33= | Silent (SNP) | VAF 32/66 reads (48%) | catalogued as rs904112917, COSV100824417; called by muse, varscan2
- OSBPL10 | c.96C>T p.S32= | Silent (SNP) | VAF 32/70 reads (46%) | catalogued as rs1307402717, COSV100824419; called by muse, varscan2
- PCDHA11 | c.1215G>A p.S405= | Silent (SNP) | VAF 57/131 reads (44%) | catalogued as rs372041974; called by muse, mutect2, varscan2
- PIM1 | c.126G>A p.P42= | Silent (SNP) | VAF 24/53 reads (45%) | catalogued as rs753629252, COSV100998677; called by muse, varscan2
- PIM1 | c.291C>T p.S97= | Silent (SNP) | VAF 23/46 reads (50%) | catalogued as COSV65165165, COSV65165406; called by muse, mutect2, varscan2
- PIM2 | c.66C>T p.G22= | Silent (SNP) | VAF 59/67 reads (88%) | catalogued as rs782077114, COSV99331992; called by muse, mutect2, varscan2
- PKP1 | c.78G>A p.P26= | Silent (SNP) | VAF 31/76 reads (41%) | catalogued as COSV99825321; called by muse, mutect2, varscan2
- PNLIPRP3 | c.612C>A p.V204= | Silent (SNP) | VAF 55/174 reads (32%) | catalogued as COSV65049909; called by muse, mutect2, varscan2
- POU2F2 | c.702C>T p.N234= (on ENST00000526816 / NM_001207025.3; = p.N218= on NM_002698.5) | Silent (SNP) | VAF 24/102 reads (24%) | catalogued as COSV100657235; called by muse, mutect2, varscan2
- PPP5C | c.462C>T p.G154= | Silent (SNP) | VAF 61/103 reads (59%) | catalogued as rs923353760, COSV50139595; called by muse, mutect2, varscan2
- RAB11B | c.291G>C p.L97= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as COSV100033103; called by muse, mutect2, varscan2
- RAB11FIP1 | c.1392A>G p.E464= | Silent (SNP) | VAF 55/127 reads (43%) | catalogued as COSV99770095; called by muse, mutect2, varscan2
- RFX1 | c.1986G>C p.L662= | Silent (SNP) | VAF 25/48 reads (52%) | catalogued as COSV99586117; called by muse, mutect2, varscan2
- ROPN1L | c.684A>C p.V228= | Silent (SNP) | VAF 125/284 reads (44%) | catalogued as COSV99928659; called by muse, mutect2, varscan2
- SCN2A | c.2811C>T p.R937= | Silent (SNP) | VAF 128/250 reads (51%) | catalogued as rs779791354, COSV51852237; ClinVar: likely benign; called by muse, mutect2, varscan2
- SEMA5A | c.1839C>T p.I613= | Silent (SNP) | VAF 33/85 reads (39%) | catalogued as rs1160987310, COSV101228346; called by muse, mutect2, varscan2
- SIRT7 | c.759G>A p.A253= | Silent (SNP) | VAF 25/62 reads (40%) | catalogued as rs773663162, COSV100155554; called by muse, mutect2, varscan2
- SLC16A7 | c.330A>G p.V110= | Silent (SNP) | VAF 9/202 reads (4%) | catalogued as COSV99676537; called by muse, mutect2
- SPATA9 | c.600G>A p.E200= | Silent (SNP) | VAF 87/197 reads (44%) | catalogued as COSV99174156; called by muse, mutect2, varscan2
- TAOK2 | c.1806C>T p.P602= | Silent (SNP) | VAF 14/25 reads (56%) | catalogued as COSV99664698; called by muse, mutect2, varscan2
- TMEM52B | c.279C>T p.H93= (on ENST00000381923 / NM_001079815.1; = p.H73= on NM_153022.4) | Silent (SNP) | VAF 23/61 reads (38%) | catalogued as rs145013082; called by muse, mutect2, varscan2
- TOM1L1 | c.739C>A p.R247= | Silent (SNP) | VAF 39/95 reads (41%) | catalogued as COSV100779218, COSV61949190; called by muse, mutect2, varscan2
- UTRN | c.9543A>G p.Q3181= | Silent (SNP) | VAF 44/58 reads (76%) | catalogued as rs1413436326, COSV100837847; called by muse, varscan2
- ZNF786 | c.675G>A p.A225= | Silent (SNP) | VAF 32/80 reads (40%) | catalogued as rs778525737, COSV60275574; called by muse, mutect2, varscan2
- AL359922.1 | c.348-35127A>G | Intron (SNP) | VAF 20/24 reads (83%) | catalogued as rs876659353, COSV100845308; ClinVar: uncertain significance; called by muse, varscan2
- ARHGEF25 | chr12:57620435 G>A | 3'Flank (SNP) | VAF 41/151 reads (27%) | catalogued as COSV54084432; called by muse, mutect2, varscan2
- MIF4GD | c.82+714G>A | Intron (SNP) | VAF 21/54 reads (39%) | catalogued as COSV99821585; called by muse, mutect2, varscan2
- TSPOAP1 | chr17:58331234 C>T | 5'Flank (SNP) | VAF 15/32 reads (47%) | called by muse, mutect2, varscan2
